Somatic mutation profile of tumor specimen 9c8e78bf-b03e-4ba0-9909-5ff070 (aliquot 9c8e78bf-b03e-4ba0-9909-5ff070_D6) from CPTAC case 04OV054, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 9c8e78bf-b03e-4ba0-9909-5ff070: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be8ebc8d-ed46-43d9-920b-73f56f42a3c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 80ee169f-1b99-4e16-b57c-085868 (Blood Derived Normal), aliquot 80ee169f-1b99-4e16-b57c-085868_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a895cc7f-293b-4519-b1e9-499f925f97ff

The open-access MAF lists 80 somatic variants for this specimen: 49 protein-altering or splice-affecting, 21 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 21, Intron 6, Frame Shift Ins 3, Splice Region 3, RNA 2, 5'UTR 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 121/164 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.3347G>A p.G1116E | Missense Mutation (SNP) | VAF 143/193 reads (74%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1291782342, COSV52031703; called by muse, mutect2, varscan2
- AGGF1 | c.2042dup p.N681Kfs*11 | Frame Shift Ins (INS) | VAF 28/83 reads (34%) | catalogued as rs761190994; called by mutect2, varscan2
- AGL | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 104/251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128732; called by muse, mutect2, varscan2
- CFAP97 | c.481dup p.S161Kfs*10 | Frame Shift Ins (INS) | VAF 41/128 reads (32%) | catalogued as rs34798240; called by mutect2, varscan2
- CHD4 | c.2830C>T p.R944W (on ENST00000357008 / NM_001363606.2; = p.R957W on NM_001273.5) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58896897; called by muse, mutect2, varscan2
- COG7 | c.1293-5G>A | Splice Region (SNP) | VAF 66/131 reads (50%) | catalogued as rs371389811; called by muse, mutect2, varscan2
- COL12A1 | c.1646C>A p.T549K | Missense Mutation (SNP) | VAF 246/536 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59408187; called by muse, mutect2, varscan2
- EGFLAM | c.2565G>A p.K855= (on ENST00000354891 / NM_001205301.2; = p.K847= on NM_152403.4) | Splice Region (SNP) | VAF 170/213 reads (80%) | catalogued as rs1436464947; called by muse, mutect2, varscan2
- FARP1 | c.2423A>G p.Y808C | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); catalogued as rs761119851; called by muse, mutect2, varscan2
- GCGR | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 240/494 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs889041091; called by mutect2, varscan2
- GEN1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754845861, COSV58057985; called by muse, mutect2, varscan2
- GNAT3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.795); catalogued as COSV68070273; called by muse, varscan2
- LCOR | c.2771G>A p.R924Q | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1435096582; called by muse, mutect2, varscan2
- MDN1 | c.8540G>A p.R2847H | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs150701881; called by muse, mutect2, varscan2
- PDE3B | c.1425C>A p.C475* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV56380806; called by muse, varscan2
- PRMT9 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); catalogued as COSV59359877; called by muse, mutect2, varscan2
- SALL3 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758753258, COSV73306062; called by muse, mutect2
- SBF1 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758712336; called by muse, mutect2, varscan2
- SLC25A14 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV99502600; called by muse, mutect2, varscan2
- SNAP25 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1481810638, COSV54770405, COSV54774288; called by muse, mutect2, varscan2
- TRIM49 | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 22/319 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs778764566; called by muse, mutect2
- TRPV1 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1444497667; called by muse, mutect2
- TTN | c.91289T>C p.I30430T (on ENST00000591111; = p.I23006T on NM_003319.4) | Missense Mutation (SNP) | VAF 49/182 reads (27%) | PolyPhen benign (0.013); catalogued as rs755545981; called by muse, mutect2, varscan2
- ZFP92 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1260472891; called by mutect2, varscan2
- ZNF615 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 164/228 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs759111853; called by muse, varscan2
- ACSS3 | c.908C>A p.T303K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AL121900.1 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC14 | c.1021T>C p.F341L (on ENST00000488653; = p.F293L on NM_022757.5) | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- COL11A1 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- COMMD4 | c.3+3G>A | Splice Region (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- DCBLD1 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 61/184 reads (33%) | called by muse, mutect2, varscan2
- DNAH9 | c.5195G>T p.G1732V | Missense Mutation (SNP) | VAF 40/620 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2
- ERICH6B | c.1489A>T p.I497L | Missense Mutation (SNP) | VAF 105/185 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FKBP7 | c.507+2T>A p.X169_splice | Splice Site (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- FSHR | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- H1-7 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 224/506 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNU1 | c.1649T>C p.M550T | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- LRP1B | c.437T>A p.I146K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LRP2 | c.9391A>G p.T3131A | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MTA2 | c.54del p.S19Afs*65 | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | called by mutect2, pindel, varscan2
- NPL | c.677dup p.T227Dfs*9 | Frame Shift Ins (INS) | VAF 32/172 reads (19%) | called by mutect2, pindel, varscan2
- PPP4R3C | c.2233G>T p.D745Y | Missense Mutation (SNP) | VAF 96/198 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM9 | c.786T>G p.N262K | Missense Mutation (SNP) | VAF 166/1937 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PTPRN | c.2551G>C p.V851L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC39A9 | c.164T>G p.V55G | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- STARD13 | c.2450C>T p.S817F (on ENST00000336934 / NM_001243476.3; = p.S699F on NM_052851.3) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIAM1 | c.2747C>T p.S916L | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AFF2 | c.2496C>T p.A832= | Silent (SNP) | VAF 101/213 reads (47%) | catalogued as rs781846522; called by muse, mutect2, varscan2
- ATP1B1 | c.117C>T p.Y39= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV100891626; called by muse, mutect2, varscan2
- CMPK2 | c.492C>T p.F164= | Silent (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- DNAH17 | c.1149C>A p.L383= | Silent (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- EID2 | c.138G>C p.A46= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, varscan2
- FCGBP | c.8181T>A p.T2727= | Silent (SNP) | VAF 252/1088 reads (23%) | called by muse, mutect2, varscan2
- FCGBP | c.4578T>A p.T1526= | Silent (SNP) | VAF 96/702 reads (14%) | called by muse, mutect2, varscan2
- GPRASP2 | c.775A>C p.R259= | Silent (SNP) | VAF 157/367 reads (43%) | called by muse, mutect2, varscan2
- GREB1L | c.273C>T p.D91= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs370170442; called by muse, mutect2, varscan2
- H2BU1 | c.246A>G p.A82= | Silent (SNP) | VAF 161/283 reads (57%) | catalogued as rs199592646, COSV64209659; called by muse, mutect2, varscan2
- IGDCC4 | c.2265C>T p.H755= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs760671350, COSV61539064; called by muse, mutect2, varscan2
- KCTD16 | c.996C>T p.P332= | Silent (SNP) | VAF 134/312 reads (43%) | catalogued as rs771594591; called by muse, mutect2, varscan2
- LYST | c.69G>T p.V23= | Silent (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- MROH7 | c.1080C>T p.A360= | Silent (SNP) | VAF 106/227 reads (47%) | called by muse, mutect2, varscan2
- PCCB | c.21G>A p.V7= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs1404763021; called by muse, mutect2, varscan2
- SEC14L2 | c.1206G>A p.P402= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs776683822, COSV56741522; called by muse, mutect2, varscan2
- SEC14L4 | c.843G>A p.T281= | Silent (SNP) | VAF 170/239 reads (71%) | catalogued as rs760802294, COSV55399798; called by muse, mutect2, varscan2
- SFRP1 | c.468G>A p.K156= | Silent (SNP) | VAF 148/241 reads (61%) | catalogued as rs1372528133; called by muse, mutect2, varscan2
- SHC1 | c.282C>T p.I94= | Silent (SNP) | VAF 92/313 reads (29%) | catalogued as rs148582449; called by muse, mutect2, varscan2
- SIGLEC5 | c.1263C>T p.G421= | Silent (SNP) | VAF 40/90 reads (44%) | called by mutect2, varscan2
- WDR17 | c.1212C>T p.D404= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as rs373229064; called by muse, mutect2, varscan2
- ADGRL4 | c.1749+9A>C | Intron (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- CCDC144NL | n.841T>C | RNA (SNP) | VAF 23/62 reads (37%) | catalogued as rs1423379564; called by muse, mutect2, varscan2
- GNAS | c.140-16dup | Intron (INS) | VAF 26/187 reads (14%) | called by mutect2, pindel, varscan2
- HBE1 | c.-267+154T>C | Intron (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- HOXD9 | c.-1A>C | 5'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46797G>A | Intron (SNP) | VAF 43/90 reads (48%) | catalogued as rs1484740322; called by muse, mutect2, varscan2
- PABPC1P2 | n.758G>C | RNA (SNP) | VAF 26/288 reads (9%) | catalogued as rs1047292763; called by muse, mutect2
- RASGRP1 | c.36-46G>A | Intron (SNP) | VAF 63/167 reads (38%) | catalogued as rs188423505; called by muse, mutect2, varscan2
- SLC4A8 | c.2172+4818C>T | Intron (SNP) | VAF 12/20 reads (60%) | catalogued as rs781370304; called by muse, varscan2
- TRAV25 | c.-3G>C | 5'UTR (SNP) | VAF 52/132 reads (39%) | called by muse, mutect2, varscan2
